TCGA case TCGA-CE-A484 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e62a728d-390f-428a-bea1-fc8c9814fb11

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 37.8 years (13,815 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 378 days (1.0 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 4; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 5; Tumor width measurement: 2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 12 days; Disease response: Tumor Free.
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CE-A484-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 430 mg.
  Slide TCGA-CE-A484-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-CE-A484-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CE-A484-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: No; Lymph nodes examined: Yes; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 5.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 378 days; disease-specific survival: no event (censored), 378 days; disease-free interval: no event (censored), 378 days; progression-free interval: no event (censored), 378 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CE-A484-01A-11D-A23T-01): tumor purity 0.91, ploidy 1.99, whole-genome doublings 0.
